CCDI case PBBKIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d08356a8-a0fb-4f41-af02-f9a30ba179db

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.8 years (1,752 days).

Biospecimens (3 samples)
- Sample 0DDCAL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDCAM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDCAN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
